Somatic mutation profile of tumor specimen TCGA-CK-6746-01A (aliquot TCGA-CK-6746-01A-11D-1835-10) from TCGA case TCGA-CK-6746, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIB; Age at diagnosis: 84.8 years (30,957 days).
Specimen TCGA-CK-6746-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) add35bd2-7015-42e0-9d89-fc55d832c809.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CK-6746-10A (Blood Derived Normal), aliquot TCGA-CK-6746-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c9a2617-7e73-4162-b946-c1df366cd8ed

The open-access MAF lists 1,433 somatic variants for this specimen: 1,113 protein-altering or splice-affecting, 293 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 743, Silent 293, Frame Shift Del 249, Frame Shift Ins 53, Nonsense Mutation 40, Intron 15, Splice Site 13, Splice Region 7, RNA 7, In Frame Del 4, Translation Start Site 3, 3'UTR 3.

Variants (750 of 1,433; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPL | c.662del p.G221Vfs*56 | Frame Shift Del (DEL) | VAF 16/35 reads (46%) | catalogued as rs769948289; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- B2M | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs1057519877, COSV62562849, COSV62563168, COSV62564729; ClinVar: likely pathogenic; called by muse, varscan2
- BCL10 | c.136dup p.I46Nfs*4 | Frame Shift Ins (INS) | VAF 18/41 reads (44%) | catalogued as rs387906351; ClinVar: pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL5A1 | c.2988dup p.G997Rfs*17 | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | catalogued as rs764693725; ClinVar: pathogenic; called by mutect2, varscan2
- FBXL3 | c.884del p.L295Yfs*25 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | catalogued as rs764008859; ClinVar: pathogenic; called by mutect2, varscan2
- FRMD7 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852212, CM074182, CM080375, COSV53745682, COSV53747620; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IQSEC2 | c.848del p.G283Afs*23 (on ENST00000642864 / NM_001111125.3; = p.G78Afs*23 on NM_015075.2) | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs782660318, COSV64726734; ClinVar: pathogenic; called by mutect2, varscan2
- LIFR | c.1789C>T p.R597* | Nonsense Mutation (SNP) | VAF 53/111 reads (48%) | catalogued as rs121912501, CM040447, COSV54684100; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 56/128 reads (44%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 22/56 reads (39%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NCSTN | c.17del p.G6Vfs*22 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs1266104510; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RAD50 | c.541del p.S181Qfs*9 | Frame Shift Del (DEL) | VAF 36/95 reads (38%) | catalogued as rs786201531; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SCN1A | c.1738C>T p.R580* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as rs794726736, CM096095, COSV57669359; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STAT5B | c.1102del p.Q368Rfs*2 | Frame Shift Del (DEL) | VAF 31/74 reads (42%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TBC1D24 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs483352866, CM146963, COSV99564594; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TSC1 | c.1257del p.R420Gfs*20 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs118203506, CD991903; ClinVar: not provided / pathogenic; called by mutect2, pindel, varscan2
- WNT4 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs121908652, COSV99268569; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.3122G>A p.R1041H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.416); catalogued as rs778906099, COSV99564893; called by muse, mutect2, varscan2
- ABCB10 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100747825; called by muse, mutect2, varscan2
- ABCC4 | c.1588G>T p.D530Y | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100972174; called by muse, mutect2, varscan2
- ABCC5 | c.2564del p.G855Afs*14 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | catalogued as rs1158884698; called by mutect2, pindel, varscan2
- ABCF3 | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV99491188; called by muse, mutect2, varscan2
- ABHD4 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.163); catalogued as COSV53530763; called by muse, mutect2, varscan2
- ABHD8 | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as COSV99917088; called by muse, mutect2, varscan2
- ABRAXAS2 | c.580A>G p.T194A | Missense Mutation (SNP) | VAF 81/213 reads (38%) | SIFT tolerated (0.79); PolyPhen benign (0.013); catalogued as COSV53718656; called by muse, mutect2, varscan2
- AC092143.1 | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs1229540455, COSV59249353; called by muse, mutect2, varscan2
- ACACA | c.6526C>T p.R2176W | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778168950; called by muse, mutect2, varscan2
- ACAD9 | c.1628T>C p.M543T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58310270; called by muse, mutect2, varscan2
- ACAP1 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs368424729, COSV50139379; called by muse, mutect2, varscan2
- ACAP2 | c.1671A>G p.S557= | Splice Region (SNP) | VAF 81/170 reads (48%) | catalogued as COSV100461263; called by muse, mutect2, varscan2
- ACR | c.659A>T p.Q220L | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV99334283; called by muse, mutect2, varscan2
- ADA | c.441G>T p.K147N | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); catalogued as COSV100866541; called by muse, mutect2, varscan2
- ADAMTS10 | c.2200A>G p.I734V | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.228); catalogued as rs143369078; called by muse, mutect2, varscan2
- ADAMTS17 | c.1721del p.P575Lfs*13 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | catalogued as rs779966272; called by mutect2, varscan2
- ADAMTS18 | c.2384G>A p.S795N | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV99270855; called by muse, mutect2, varscan2
- ADAMTS5 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs1451753138, COSV99536872; called by muse, mutect2
- ADAMTS9 | c.4539T>G p.C1513W | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99898446; called by muse, mutect2, varscan2
- ADAMTSL5 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs1227665930, COSV100389025; called by muse, mutect2, varscan2
- ADCY8 | c.2387A>C p.N796T | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV99650180; called by muse, varscan2
- ADCY8 | c.2314C>T p.R772W | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs749479126, COSV53898899, COSV99653918; called by muse, varscan2
- ADCY9 | c.1487T>G p.L496R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99569149; called by muse, mutect2, varscan2
- ADGRL3 | c.1189G>A p.D397N (on ENST00000506720 / NM_001322402.2; = p.D329N on NM_015236.6) | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780445734, COSV72273949; called by muse, mutect2, varscan2
- ADRA1A | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.849); catalogued as COSV52364402; called by muse, mutect2, varscan2
- AFF2 | c.2431T>C p.S811P | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54008783; called by muse, mutect2, varscan2
- AFMID | c.650A>C p.D217A | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.393); catalogued as COSV100014755; called by muse, mutect2, varscan2
- AGO1 | c.1996C>T p.R666* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as rs1213741177, COSV100940728; called by muse, mutect2, varscan2
- AHNAK | c.13927G>A p.V4643I | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.96); catalogued as rs750676449, COSV99945178; called by muse, mutect2, varscan2
- AHNAK | c.9689G>A p.G3230D | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV57204246; called by muse, mutect2, varscan2
- ALDH1A3 | c.849del p.K284Rfs*83 | Frame Shift Del (DEL) | VAF 30/88 reads (34%) | catalogued as rs758955164; called by mutect2, pindel, varscan2
- ALG8 | c.329T>C p.V110A | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100219916; called by muse, mutect2, varscan2
- ALMS1 | c.11204C>T p.S3735L | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); catalogued as rs367877017, CM074702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALS2 | c.2581-1G>T p.X861_splice | Splice Site (SNP) | VAF 26/54 reads (48%) | catalogued as COSV99968548; called by muse, mutect2, varscan2
- AMACR | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.111); catalogued as COSV100162762; called by muse, mutect2, varscan2
- AMER2 | c.292A>G p.T98A | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100766097; called by muse, mutect2, varscan2
- AMIGO3 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs760910986, COSV100246387; called by muse, mutect2, varscan2
- ANK2 | c.7043C>T p.A2348V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.023); catalogued as rs1297163090, COSV99998911; called by muse, mutect2, varscan2
- ANKEF1 | c.770A>G p.Y257C | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV101000960; called by muse, mutect2, varscan2
- ANKRD10 | c.456-1G>A p.X152_splice | Splice Site (SNP) | VAF 23/57 reads (40%) | catalogued as COSV57445741; called by muse, mutect2, varscan2
- ANKRD11 | c.7150C>T p.P2384S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99968008; called by muse, mutect2, varscan2
- ANKRD34A | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60162130; called by muse, mutect2, varscan2
- ANKRD37 | c.182A>G p.D61G | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV99248785; called by muse, mutect2, varscan2
- ANKS1A | c.959dup p.P321Tfs*19 | Frame Shift Ins (INS) | VAF 45/140 reads (32%) | catalogued as rs761903319; called by mutect2, varscan2
- AP1B1 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756663659, COSV100434281; called by muse, mutect2, varscan2
- APLF | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV100376267; called by muse, mutect2, varscan2
- ARAP3 | c.4412C>A p.S1471* | Nonsense Mutation (SNP) | VAF 24/52 reads (46%) | catalogued as COSV99499199; called by muse, mutect2, varscan2
- ARHGAP36 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs1256533982, COSV52267805, COSV99357197; called by muse, mutect2, varscan2
- ARHGAP39 | c.2492G>A p.R831Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs993549396, COSV52775333, COSV99430098; called by muse, mutect2, varscan2
- ARHGAP4 | c.776A>T p.N259I | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV63131029, COSV63134769; called by muse, mutect2, varscan2
- ARHGEF15 | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193921031, COSV62725197; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF18 | c.878T>C p.V293A (on ENST00000359920 / NM_001130955.2; = p.V189A on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV100148847; called by muse, mutect2, varscan2
- ARHGEF18 | c.3134G>A p.R1045H (on ENST00000359920 / NM_001130955.2; = p.R941H on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs145300154; called by muse, mutect2, varscan2
- ARHGEF25 | c.92del p.G31Dfs*48 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | catalogued as rs748506876, COSV99677997; called by mutect2, pindel, varscan2
- ARHGEF26 | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62852320; called by muse, mutect2, varscan2
- ARID1B | c.6244A>G p.N2082D | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99266520; called by muse, mutect2, varscan2
- ARMC3 | c.2049A>C p.K683N | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99957267; called by muse, mutect2, varscan2
- ARPP21 | c.1286T>C p.L429P | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV99490498; called by muse, mutect2, varscan2
- ARSD | c.987G>A p.M329I | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99471887, COSV99472451; called by muse, mutect2, varscan2
- ASAP3 | c.767A>G p.D256G | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100369108; called by muse, mutect2, varscan2
- ASIC4 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.358); catalogued as rs138559599; called by muse, mutect2, varscan2
- ASTN1 | c.3716C>T p.P1239L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.33); catalogued as rs757918315, COSV100705263; called by muse, mutect2, varscan2
- ASTN1 | c.2357C>A p.P786H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99920095; called by muse, mutect2, varscan2
- ASXL2 | c.2674A>G p.T892A | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV99709948; called by muse, mutect2, varscan2
- ATG9B | c.2162del p.P721Qfs*62 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as COSV52486004; called by mutect2, pindel, varscan2
- ATP1B2 | c.215A>C p.K72T | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV51516850; called by muse, mutect2, varscan2
- ATP2A1 | c.2008T>C p.C670R | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as COSV100706762; called by muse, mutect2, varscan2
- ATP2A2 | c.2029C>T p.R677* | Nonsense Mutation (SNP) | VAF 24/47 reads (51%) | catalogued as CM990246, COSV100428322; called by muse, mutect2, varscan2
- ATP2B1 | c.2097G>T p.R699S | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.523); catalogued as COSV53804166, COSV99665058; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1443883930, CM023021, CM165616, COSV59477440; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1219G>A p.V407M | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100022458; called by muse, mutect2, varscan2
- ATRX | c.6001T>C p.W2001R | Missense Mutation (SNP) | VAF 106/239 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64884036; called by muse, mutect2, varscan2
- B3GNT6 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.045); catalogued as rs782692000; called by muse, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs35951843; called by mutect2, pindel, varscan2
- BARHL2 | c.770T>C p.L257P | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100966007; called by muse, mutect2, varscan2
- BAZ2B | c.1739A>G p.H580R | Missense Mutation (SNP) | VAF 71/188 reads (38%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV100600263; called by muse, mutect2, varscan2
- BCL11B | c.2386G>A p.D796N (on ENST00000357195 / NM_001282237.2; = p.D725N on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61737153; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BOC | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.097); catalogued as rs1269389532, COSV99847822; called by muse, mutect2, varscan2
- BOD1L1 | c.4520C>T p.T1507I | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.035); catalogued as COSV99238116; called by muse, mutect2, varscan2
- BRCA2 | c.7307A>G p.N2436S | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.889); catalogued as rs80358955, CD118926, COSV101203824; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD2 | c.1784del p.G595Vfs*6 | Frame Shift Del (DEL) | VAF 37/80 reads (46%) | catalogued as rs1384569924; called by mutect2, pindel, varscan2
- BRF1 | c.876dup p.S293Lfs*15 | Frame Shift Ins (INS) | VAF 10/28 reads (36%) | catalogued as rs747435524; called by mutect2, varscan2
- BRWD3 | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100955559; called by muse, mutect2, varscan2
- BTNL9 | c.592T>C p.F198L | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs758793047, COSV59799659; called by muse, mutect2, varscan2
- C10orf120 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs189569073, COSV61492374; called by muse, mutect2, varscan2
- C12orf66 | c.1103T>C p.M368T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV100320489; called by muse, mutect2, varscan2
- C14orf39 | c.1349dup p.F451Vfs*4 | Frame Shift Ins (INS) | VAF 34/74 reads (46%) | catalogued as rs776870689; called by mutect2, varscan2
- C15orf39 | c.2633T>C p.L878P | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100641145; called by muse, mutect2, varscan2
- C17orf97 | c.1080G>T p.E360D | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV64077532; called by muse, mutect2, varscan2
- C1QTNF1 | c.158C>A p.A53D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV100189675; called by muse, mutect2, varscan2
- C2CD5 | c.2902G>A p.A968T | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as rs759062171, COSV61725901; called by muse, mutect2, varscan2
- C3orf20 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs145497672; called by muse, mutect2, varscan2
- CA7 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100623696; called by muse, mutect2, varscan2
- CABP4 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs374363909, COSV57800416; called by muse, mutect2, varscan2
- CACHD1 | c.3704dup p.Q1236Sfs*23 | Frame Shift Ins (INS) | VAF 24/72 reads (33%) | catalogued as rs764948820; called by mutect2, varscan2
- CACNA1C | c.3724G>A p.G1242S | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs1131691881, COSV100214273; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.2731C>T p.R911W | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs370013304, COSV62390334; called by muse, mutect2, varscan2
- CACNA1F | c.4471C>A p.P1491T | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100544239; called by muse, mutect2, varscan2
- CACNA1S | c.1747G>T p.G583W | Missense Mutation (SNP) | VAF 87/209 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100754531, COSV100754902; called by muse, mutect2, varscan2
- CACNA2D1 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 112/239 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as COSV100665302, COSV100666693; called by muse, mutect2, varscan2
- CACNB2 | c.1420C>A p.P474T (on ENST00000324631 / NM_201596.3; = p.P419T on NM_000724.4) | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV99992492; called by muse, mutect2, varscan2
- CAMKV | c.348C>A p.Y116* | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | catalogued as COSV56557954; called by muse, mutect2, varscan2
- CANT1 | c.44T>C p.M15T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as rs1226007813, COSV100185112; called by muse, mutect2, varscan2
- CARF | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.054); catalogued as rs1457032233, COSV57550100; called by muse, mutect2, varscan2
- CARMIL2 | c.4121G>A p.R1374Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); catalogued as rs1372728652, COSV54667398; called by muse, mutect2, varscan2
- CASKIN2 | c.1016del p.P339Rfs*95 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | catalogued as COSV100050703; called by mutect2, pindel, varscan2
- CASP1 | c.614del p.N205Ifs*7 (on ENST00000436863 / NM_033292.4; = p.N184Ifs*7 on NM_001223.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 42/110 reads (38%) | catalogued as rs746543598, COSV62056860; called by mutect2, varscan2
- CASS4 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs139063252; called by muse, mutect2, varscan2
- CATSPER4 | c.1401del p.K467Nfs*78 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs769908264; called by mutect2, pindel, varscan2
- CBR4 | c.141C>T p.G47= | Splice Region (SNP) | VAF 13/25 reads (52%) | catalogued as COSV60370966; called by muse, mutect2, varscan2
- CCDC180 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV100826500; called by muse, mutect2, varscan2
- CCDC181 | c.1265dup p.H423Afs*24 (on ENST00000367806 / NM_001300969.1; = p.H422Afs*24 on NM_021179.2) | Frame Shift Ins (INS) | VAF 73/202 reads (36%) | catalogued as rs759258977; called by mutect2, varscan2
- CCNQ | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1178567203, COSV99367845; called by muse, mutect2, varscan2
- CCR5 | c.140G>A p.G47D | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99433024; called by muse, mutect2, varscan2
- CCRL2 | c.287A>G p.H96R | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as COSV100644949; called by muse, mutect2, varscan2
- CCS | c.285del p.P96Lfs*13 | Frame Shift Del (DEL) | VAF 21/48 reads (44%) | catalogued as rs759691599; called by mutect2, pindel, varscan2
- CD163L1 | c.1408G>C p.D470H | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100549508; called by muse, mutect2, varscan2
- CD93 | c.943dup p.A315Gfs*34 | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | catalogued as rs747115137; called by mutect2, varscan2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 9/17 reads (53%) | catalogued as rs762805003; called by mutect2, varscan2
- CDAN1 | c.2984G>A p.R995H | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369919247; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDC42BPG | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142811739; called by muse, mutect2, varscan2
- CDH17 | c.1899T>A p.Y633* | Nonsense Mutation (SNP) | VAF 41/74 reads (55%) | catalogued as COSV99216787; called by muse, mutect2, varscan2
- CDH4 | c.368A>G p.Q123R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as rs757506706, COSV100848245; called by muse, mutect2, varscan2
- CDH8 | c.2345G>A p.R782H | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs772878546, COSV54867033; called by muse, mutect2, varscan2
- CDK1 | c.791T>C p.L264P | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100358741; called by muse, mutect2, varscan2
- CDR2L | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as rs892939625, COSV61501911; called by muse, mutect2, varscan2
- CDRT1 | c.1781G>A p.G594D | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63052410; called by muse, mutect2, varscan2
- CDS2 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761127363, COSV66896469; called by muse, mutect2, varscan2
- CECR2 | c.3647A>G p.H1216R (on ENST00000342247 / NM_001290047.2; = p.H1032R on NM_001290046.1) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.502); catalogued as rs551944084, COSV99376744; called by muse, mutect2, varscan2
- CELSR3 | c.5802del p.S1935Afs*4 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as rs1205203585, COSV50840268; called by mutect2, pindel, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 116/317 reads (37%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CENPW | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 19/51 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.423); catalogued as COSV100851372; called by muse, mutect2, varscan2
- CEP164 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99632351; called by muse, mutect2, varscan2
- CEP170 | c.3911G>T p.R1304M | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100316240; called by muse, mutect2, varscan2
- CEP97 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs145086802; called by muse, mutect2, varscan2
- CFAP410 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs553278564, COSV100297069; called by muse, mutect2, varscan2
- CHD3 | c.332del p.K111Rfs*30 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | catalogued as rs1382061552; called by mutect2, pindel, varscan2
- CHD4 | c.5615C>T p.A1872V (on ENST00000357008 / NM_001363606.2; = p.A1882V on NM_001273.5) | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58911153; called by muse, mutect2, varscan2
- CHRDL1 | c.575C>T p.A192V (on ENST00000372045; = p.A198V on NM_145234.4) | Missense Mutation (SNP) | VAF 128/280 reads (46%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.978); catalogued as COSV99487604; called by muse, varscan2
- CHST15 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.837); catalogued as rs202236206, COSV60562996; called by muse, mutect2, varscan2
- CIART | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs147269137; called by muse, mutect2, varscan2
- CIITA | c.1962dup p.G655Rfs*94 | Frame Shift Ins (INS) | VAF 14/31 reads (45%) | catalogued as rs778982759; called by mutect2, varscan2
- CLCA2 | c.1489-2A>C p.X497_splice | Splice Site (SNP) | VAF 23/58 reads (40%) | catalogued as COSV100991266; called by muse, mutect2, varscan2
- CLIP2 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99790839; called by muse, mutect2, varscan2
- CLP1 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as rs1443018290, COSV57054867; called by muse, mutect2, varscan2
- CLPP | c.750G>T p.Q250H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV99831957; called by muse, mutect2, varscan2
- CMTM3 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV62680487; called by muse, mutect2, varscan2
- CNKSR1 | c.1535dup p.P513Tfs*9 (on ENST00000374253 / NM_001297647.2; = p.P506Tfs*9 on NM_006314.3) | Frame Shift Ins (INS) | VAF 12/27 reads (44%) | catalogued as rs753922055; called by mutect2, varscan2
- CNOT1 | c.6802A>C p.N2268H | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99542957; called by muse, mutect2, varscan2
- CNOT1 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.446); catalogued as COSV57780995; called by muse, mutect2, varscan2
- CNTRL | c.5322G>C p.E1774D | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as rs576226225, COSV53053846; called by muse, mutect2, varscan2
- COG7 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as rs1320314614, COSV56149574; called by muse, mutect2, varscan2
- COL11A1 | c.3777A>C p.E1259D | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV62198861; called by muse, mutect2, varscan2
- COL1A1 | c.3540del p.G1181Afs*58 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | catalogued as CD1110814; called by mutect2, varscan2
- COL4A1 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101010911; called by muse, mutect2, varscan2
- COL9A1 | c.1187del p.P396Qfs*33 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs983596283; called by mutect2, pindel, varscan2
- COPG1 | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.935); catalogued as rs775881986, COSV59113994, COSV59116677; called by muse, mutect2, varscan2
- COX19 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV100700386; called by muse, mutect2, varscan2
- COX4I1 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs201058411, COSV53665895; called by muse, mutect2, varscan2
- CPXM1 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756881556, COSV66045153; called by muse, mutect2, varscan2
- CPXM2 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV53858279; called by muse, mutect2, varscan2
- CR1L | c.486del p.T163Pfs*21 | Frame Shift Del (DEL) | VAF 43/148 reads (29%) | catalogued as rs765293717; called by mutect2, pindel, varscan2
- CRADD | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as COSV100257268; called by muse, mutect2, varscan2
- CSMD1 | c.7403G>A p.G2468D (on ENST00000520002; = p.G2467D on NM_033225.6) | Missense Mutation (SNP) | VAF 46/75 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100142023, COSV59328437; called by muse, mutect2, varscan2
- CSMD1 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.805); catalogued as COSV101212170; called by muse, mutect2, varscan2
- CTNNA1 | c.543del p.K181Nfs*7 | Frame Shift Del (DEL) | VAF 64/190 reads (34%) | catalogued as COSV57077607; called by mutect2, pindel, varscan2
- CTNNA1 | c.2689C>A p.L897I | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100241950; called by muse, mutect2, varscan2
- CTNNBL1 | c.172del p.R58Gfs*25 | Frame Shift Del (DEL) | VAF 15/34 reads (44%) | catalogued as rs761516328; called by mutect2, pindel, varscan2
- CTSB | c.97T>C p.Y33H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as rs770370292, COSV100565788; called by muse, mutect2, varscan2
- CUL2 | c.128A>G p.Y43C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66081285; called by muse, mutect2, varscan2
- CUL9 | c.1676C>T p.T559I | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs537714187, COSV99334547; called by muse, mutect2, varscan2
- CXCL8 | c.*5del | Frame Shift Del (DEL) | VAF 94/240 reads (39%) | catalogued as rs201169323; called by mutect2, varscan2
- CYP2W1 | c.98del p.P33Rfs*24 | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | catalogued as rs745432053; called by mutect2, varscan2
- CYP46A1 | c.1351A>G p.M451V | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as COSV99952340; called by muse, mutect2, varscan2
- DAPK3 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1438429756, COSV100009419; called by muse, mutect2, varscan2
- DARS2 | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.055); catalogued as COSV53409322; called by muse, mutect2, varscan2
- DCAF13 | c.1046T>A p.I349N | Missense Mutation (SNP) | VAF 61/220 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99884891; called by muse, mutect2, varscan2
- DCAF16 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.542); catalogued as COSV101200382; called by muse, mutect2, varscan2
- DCAF4L2 | c.126T>A p.Y42* | Nonsense Mutation (SNP) | VAF 66/255 reads (26%) | catalogued as COSV100150382; called by muse, mutect2, varscan2
- DCDC1 | c.3151C>A p.Q1051K (on ENST00000597505 / NM_001367979.1; = p.Q158K on NM_020869.3) | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV60313323; called by muse, mutect2, varscan2
- DCN | c.563G>T p.S188I | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99271662; called by muse, mutect2, varscan2
- DCPS | c.560A>G p.D187G | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99703305; called by muse, varscan2
- DCTN3 | c.164A>G p.K55R | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV99426671; called by muse, mutect2, varscan2
- DDX50 | c.1609G>A p.V537I | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); catalogued as rs748915927, COSV65293433; called by muse, mutect2, varscan2
- DDX60L | c.3739T>C p.Y1247H | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs752990217, COSV99486749; called by muse, mutect2, varscan2
- DENND4B | c.22dup p.R8Pfs*20 | Frame Shift Ins (INS) | VAF 6/14 reads (43%) | catalogued as rs755611865; called by mutect2, varscan2
- DHRS2 | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99158670; called by muse, mutect2, varscan2
- DIO3 | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100831999; called by muse, mutect2, varscan2
- DIP2A | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 98/229 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as rs765532031, COSV59480991; called by mutect2, varscan2
- DLGAP1 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1258270976, COSV59814670; called by muse, mutect2, varscan2
- DLGAP2 | c.922A>G p.T308A | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.99); catalogued as COSV101420973; called by muse, mutect2, varscan2
- DLGAP3 | c.1158G>T p.E386D | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.874); catalogued as COSV99332020; called by muse, mutect2, varscan2
- DLX5 | c.158del p.G53Efs*28 | Frame Shift Del (DEL) | VAF 26/67 reads (39%) | catalogued as COSV56034256; called by mutect2, pindel, varscan2
- DMD | c.9569G>A p.R3190Q | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766768395, COSV58939355; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMD | c.8086del p.L2696Wfs*30 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs398124062, CD961958; called by mutect2, varscan2
- DMXL2 | c.326dup p.L109Ffs*15 | Frame Shift Ins (INS) | VAF 51/144 reads (35%) | catalogued as rs752363479; called by mutect2, varscan2
- DNA2 | c.2321G>C p.G774A | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.936); catalogued as COSV64430358; called by muse, mutect2, varscan2
- DNAAF1 | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.8); catalogued as rs1416252664, COSV99550216; called by muse, mutect2, varscan2
- DNAH1 | c.7912C>T p.P2638S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs764387399, COSV101324354; called by muse, mutect2, varscan2
- DNAH7 | c.10024A>C p.T3342P | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV100413412; called by muse, mutect2, varscan2
- DNAH9 | c.10612A>G p.I3538V | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.173); catalogued as COSV99303192; called by muse, mutect2, varscan2
- DNAJA3 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753693250, COSV99276332; called by muse, mutect2, varscan2
- DNAJC7 | c.527A>G p.H176R | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.026); catalogued as COSV57270516; called by muse, mutect2, varscan2
- DOCK5 | c.1403T>A p.V468E | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99375804; called by muse, mutect2, varscan2
- DPEP3 | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV99262531; called by muse, mutect2, varscan2
- DPP10 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59731813; called by muse, mutect2, varscan2
- DPY19L4 | c.1480G>A p.V494M | Missense Mutation (SNP) | VAF 63/244 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.102); catalogued as COSV101363028; called by muse, mutect2, varscan2
- DSE | c.2361G>T p.E787D | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); catalogued as COSV100528249; called by muse, mutect2, varscan2
- DSEL | c.1991C>G p.A664G | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs1223141100, COSV100025105; called by muse, mutect2, varscan2
- DST | c.1066A>G p.N356D | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55041506; called by muse, varscan2
- DYNC2I1 | c.1580del p.N527Ifs*23 | Frame Shift Del (DEL) | VAF 42/108 reads (39%) | catalogued as rs751377941; called by mutect2, varscan2
- DYNC2I2 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as COSV101020957; called by muse, mutect2, varscan2
- DYRK1B | c.1633dup p.Q545Pfs*30 | Frame Shift Ins (INS) | VAF 8/18 reads (44%) | catalogued as rs775499198; called by mutect2, varscan2
- E2F7 | c.314del p.K105Rfs*43 | Frame Shift Del (DEL) | VAF 74/234 reads (32%) | catalogued as COSV59740114; called by pindel, varscan2
- E2F8 | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs755274793, COSV100001230; called by muse, mutect2, varscan2
- EBNA1BP2 | c.280A>C p.K94Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.157); catalogued as COSV99355784; called by muse, mutect2, varscan2
- ECPAS | c.3430G>A p.V1144I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV99397293; called by muse, mutect2, varscan2
- EGFLAM | c.1717T>C p.S573P | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV100379587; called by muse, mutect2, varscan2
- EHD2 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54407896, COSV99621506; called by muse, mutect2, varscan2
- EHHADH | c.1657A>G p.R553G | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV51633732; called by muse, mutect2, varscan2
- EHMT1 | c.1889G>A p.C630Y | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100603432; called by muse, mutect2, varscan2
- EHMT1 | c.2491C>A p.L831M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.617); catalogued as COSV100603437; called by muse, mutect2, varscan2
- EIF4A2 | c.1067A>C p.N356T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.153); catalogued as COSV99960922; called by muse, mutect2, varscan2
- EIF4E | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as rs772918368, COSV99794595; called by muse, mutect2, varscan2
- EIF4G2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as COSV100379322; called by muse, mutect2, varscan2
- ELAVL3 | c.47del p.G16Afs*35 | Frame Shift Del (DEL) | VAF 28/68 reads (41%) | catalogued as rs751148694; called by mutect2, varscan2
- ELOA | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 35/73 reads (48%) | catalogued as COSV101403571; called by muse, mutect2, varscan2
- ENG | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs761827492, COSV100785188; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ENO2 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.192); catalogued as rs781871089, COSV99980093; called by muse, mutect2, varscan2
- ENTPD7 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 110/279 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.09); catalogued as rs756842180, COSV100978327; called by muse, mutect2, varscan2
- EOMES | c.223G>C p.A75P | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.029); catalogued as rs1174591076, COSV99841607; called by muse, mutect2, varscan2
- EP400 | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.241); catalogued as COSV57769690; called by muse, mutect2, varscan2
- EPB41L3 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 87/238 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1308048815, COSV100547950, COSV59451466; called by muse, mutect2, varscan2
- EPHA3 | c.2702T>G p.L901R | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.997); catalogued as COSV100341834; called by muse, mutect2, varscan2
- EPRS1 | c.3060del p.E1021Kfs*17 | Frame Shift Del (DEL) | VAF 95/253 reads (38%) | catalogued as rs1394740497; called by mutect2, varscan2
- EPX | c.1862A>G p.E621G | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99836157; called by muse, mutect2, varscan2
- ERAP1 | c.380del p.R127Lfs*48 | Frame Shift Del (DEL) | VAF 34/87 reads (39%) | catalogued as CM094298, COSV57088529, COSV57091247; called by mutect2, varscan2
- ERBB3 | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775164134, COSV57247893, COSV57261351; called by muse, mutect2, varscan2
- ERBIN | c.597+1G>T p.X199_splice | Splice Site (SNP) | VAF 48/154 reads (31%) | catalogued as COSV99395614; called by muse, mutect2
- ERCC3 | c.319G>T p.V107L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV99572974; called by mutect2, varscan2
- ERG28 | c.52A>G p.I18V | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV54044746; called by muse, mutect2, varscan2
- ERICH3 | c.1468C>T p.Q490* | Nonsense Mutation (SNP) | VAF 92/201 reads (46%) | catalogued as COSV100443104; called by muse, mutect2, varscan2
- ERICH6 | c.161A>T p.E54V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs753770853, COSV55798938; called by muse, mutect2, varscan2
- ERN2 | c.1399del p.L467Wfs*48 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | catalogued as rs763540496, COSV99078581; called by mutect2, pindel, varscan2
- ESPL1 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV99228728; called by muse, mutect2, varscan2
- ESYT1 | c.1759C>G p.L587V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV99919568; called by muse, mutect2, varscan2
- EVC2 | c.3273T>G p.C1091W | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100184735; called by muse, mutect2, varscan2
- EVI5L | c.1981C>T p.R661W | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs867558820, COSV99562772; called by muse, mutect2, varscan2
- EXO1 | c.333del p.V112Sfs*22 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs1364409897; called by mutect2, pindel, varscan2
- EXOC6B | c.2071C>A p.L691I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55573899; called by muse, mutect2, varscan2
- F12 | c.573G>T p.E191D | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.438); catalogued as COSV99499359; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 25/66 reads (38%) | catalogued as rs751966944; called by mutect2, varscan2
- FAM114A1 | c.496A>C p.N166H | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100729105; called by muse, mutect2, varscan2
- FAM184A | c.1558A>C p.K520Q | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.802); catalogued as COSV100137265; called by muse, mutect2, varscan2
- FAM214B | c.440del p.P147Hfs*50 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as COSV59715297; called by mutect2, pindel, varscan2
- FAM47B | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs770232500, COSV61453452; called by muse, mutect2, varscan2
- FAM83G | c.1367G>A p.S456N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1294721426, COSV100524700; called by muse, mutect2, varscan2
- FANCA | c.2915del p.G972Afs*17 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as CM164610; called by mutect2, pindel, varscan2
- FANCD2 | c.1129C>T p.H377Y | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs993186586, COSV99810113; called by muse, mutect2, varscan2
- FANCG | c.1060T>C p.C354R | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100734054; called by muse, mutect2, varscan2
- FARSA | c.437del p.G146Dfs*14 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | catalogued as rs746493788; called by mutect2, pindel, varscan2
- FASN | c.6562C>T p.Q2188* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV60751183; called by muse, mutect2, varscan2
- FBF1 | c.2752A>G p.T918A (on ENST00000586717; = p.T932A on NM_001319193.1) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.361); catalogued as COSV100044649; called by muse, mutect2, varscan2
- FBN2 | c.4621A>G p.N1541D | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV52546500; called by muse, varscan2
- FBN3 | c.4730del p.G1577Vfs*72 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as COSV54462674; called by mutect2, pindel, varscan2
- FBXO16 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 72/246 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100672043; called by muse, mutect2, varscan2
- FBXW7 | c.1730T>C p.L577S (on ENST00000281708 / NM_001349798.2; = p.L497S on NM_018315.5) | Missense Mutation (SNP) | VAF 70/83 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99653583; called by muse, mutect2, varscan2
- FGD6 | c.2307A>G p.I769M | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100676307; called by muse, mutect2, varscan2
- FHOD1 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV50759244; called by muse, mutect2, varscan2
- FNBP4 | c.1766T>C p.L589P | Missense Mutation (SNP) | VAF 84/240 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99771343; called by muse, mutect2, varscan2
- FNDC4 | c.318G>T p.W106C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53022510; called by muse, mutect2, varscan2
- FOXA2 | c.709C>T p.P237S (on ENST00000377115 / NM_153675.3; = p.P243S on NM_021784.5) | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs760812511, COSV65797167; called by muse, mutect2, varscan2
- FRAS1 | c.11285G>C p.R3762T | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53650935; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FRMD6 | c.576del p.K193Rfs*5 (on ENST00000344768 / NM_001267046.2; = p.K185Rfs*5 on NM_152330.4) | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | catalogued as COSV100656411; called by mutect2, pindel, varscan2
- FZD9 | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554563556, COSV60671256; called by muse, mutect2, varscan2
- GAB4 | c.153dup p.E52Rfs*22 | Frame Shift Ins (INS) | VAF 45/160 reads (28%) | catalogued as rs764879401; called by mutect2, pindel*, varscan2
- GABRG3 | c.615_616insC p.N206Qfs*7 | Frame Shift Ins (INS) | VAF 30/97 reads (31%) | catalogued as COSV100403824; called by mutect2, pindel, varscan2
- GABRQ | c.94T>C p.F32L | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.34); catalogued as COSV100941062; called by muse, mutect2, varscan2
- GADL1 | c.1201G>A p.G401S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99243599; called by muse, mutect2, varscan2
- GALM | c.959T>C p.F320S | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99696905; called by muse, mutect2, varscan2
- GALNT2 | c.851A>G p.Y284C | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV64194150; called by muse, mutect2, varscan2
- GALNT7 | c.1145A>G p.Y382C | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758257810, COSV99396772; called by muse, mutect2, varscan2
- GALR2 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57162444; called by muse, mutect2, varscan2
- GAS2L1 | c.1839del p.P614Hfs*2 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | catalogued as rs78929040; called by pindel, varscan2
- GAS2L3 | c.1346C>A p.A449D | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV99902637; called by muse, mutect2, varscan2
- GAS7 | c.400G>A p.A134T (on ENST00000432992 / NM_201433.2; = p.A74T on NM_201432.2) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs1266349442, COSV60432198; called by muse, mutect2, varscan2
- GASK1B | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141301679, COSV99647169; called by muse, mutect2, varscan2
- GATA3 | c.708del p.S237Afs*28 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as rs771019738, COSV60522496; called by mutect2, pindel, varscan2
- GBE1 | c.971G>A p.S324N | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs764115648, COSV70103176; called by muse, mutect2, varscan2
- GCLC | c.983A>G p.K328R (on ENST00000643939; = p.K326R on NM_001498.4) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99988223, COSV99988337; called by muse, mutect2, varscan2
- GCNT4 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs745887897, COSV59281715; called by muse, mutect2, varscan2
- GIMAP7 | c.149C>A p.A50E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as COSV57960785; called by muse, mutect2, varscan2
- GJA8 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99568989; called by muse, mutect2, varscan2
- GLB1L | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.923); catalogued as COSV99850185; called by muse, mutect2, varscan2
- GLB1L2 | c.1571A>C p.D524A | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV100335039; called by muse, mutect2, varscan2
- GNAZ | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.037); catalogued as rs1315151887, COSV99320327; called by muse, mutect2, varscan2
- GNE | c.2140A>G p.I714V (on ENST00000396594 / NM_001128227.3; = p.I683V on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.028); catalogued as COSV64953185; called by muse, mutect2, varscan2
- GOLGA5 | c.10T>C p.F4L | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99370628; called by muse, mutect2, varscan2
- GP6 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.647); catalogued as rs756588702, COSV100117341; called by muse, mutect2, varscan2
- GPBP1L1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs768034229, COSV51970592; called by muse, mutect2, varscan2
- GPNMB | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as COSV51699969, COSV99326174; called by muse, mutect2, varscan2
- GPR142 | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV59518929, COSV59520310; called by muse, mutect2, varscan2
- GPR171 | c.226G>T p.G76C | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99851059; called by muse, mutect2, varscan2
- GPR35 | c.513C>A p.N171K | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as COSV100166245; called by muse, mutect2, varscan2
- GPR88 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV100159390; called by muse, mutect2
- GPRASP1 | c.2899G>A p.A967T | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100850886, COSV100851020; called by muse, mutect2, varscan2
- GRHL3 | c.223A>G p.I75V (on ENST00000350501 / NM_198174.3; = p.I80V on NM_021180.3) | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as COSV99358934; called by muse, mutect2, varscan2
- GRHPR | c.241A>G p.M81V | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV100546775; called by muse, mutect2, varscan2
- GRID1 | c.2212G>A p.A738T | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs911358725, COSV100021188; called by muse, mutect2, varscan2
- GRID1 | c.236C>A p.A79D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV100021190; called by muse, mutect2, varscan2
- GRID2 | c.34G>A p.V12I | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs757472665, COSV56206934; called by muse, varscan2
- GRIN2A | c.2018C>A p.P673H | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100407591; called by muse, mutect2, varscan2
- GRM8 | c.2158del p.H720Tfs*12 | Frame Shift Del (DEL) | VAF 38/94 reads (40%) | catalogued as COSV58842099; called by mutect2, varscan2
- GRN | c.674C>A p.P225H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99274483; called by muse, mutect2, varscan2
- GSTM3 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as rs1466335443, COSV99860129; called by muse, mutect2, varscan2
- GSTT2B | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 44/254 reads (17%) | catalogued as COSV99320990; called by muse, mutect2, varscan2
- GTPBP1 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.3); catalogued as rs1292737701, COSV99322832; called by muse, mutect2, varscan2
- GYS1 | c.1825C>T p.R609C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs957644060, COSV99620285; called by muse, mutect2, varscan2
- HADHB | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372980146; called by muse, mutect2, varscan2
- HAUS1 | c.146G>T p.R49M | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99958685; called by muse, mutect2, varscan2
- HAUS5 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs764338970, COSV52550009; called by muse, mutect2, varscan2
- HAUS6 | c.1475del p.N492Mfs*50 | Frame Shift Del (DEL) | VAF 101/319 reads (32%) | catalogued as rs1360468258; called by mutect2, pindel, varscan2
- HBS1L | c.1871C>T p.T624M | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs779153204, COSV63202896; called by muse, mutect2, varscan2
- HCFC1 | c.1100del p.P367Qfs*16 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as COSV100129717; called by mutect2, varscan2
- HDC | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.292); catalogued as COSV99983740; called by muse, mutect2, varscan2
- HEATR5B | c.1744C>T p.R582* | Nonsense Mutation (SNP) | VAF 27/77 reads (35%) | catalogued as COSV51854960, COSV51856853; called by muse, mutect2, varscan2
- HECW2 | c.2318A>G p.Q773R | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.011); catalogued as COSV99645413; called by muse, mutect2, varscan2
- HERC2 | c.13267A>G p.I4423V | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as COSV99870132; called by muse, mutect2, varscan2
- HMCN1 | c.6029-1G>T p.X2010_splice | Splice Site (SNP) | VAF 50/144 reads (35%) | catalogued as COSV99622601; called by muse, mutect2, varscan2
- HNF4A | c.56T>C p.L19P | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100290922; called by muse, mutect2, varscan2
- HNF4A | c.1199C>T p.T400I | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.163); catalogued as COSV100290925; called by muse, mutect2, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 22/40 reads (55%) | catalogued as rs767148651; called by mutect2, varscan2
- HOXA10 | c.1174A>C p.K392Q | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99385203; called by muse, mutect2, varscan2
- HPS6 | c.1674del p.N559Mfs*54 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs764867254; called by mutect2, pindel, varscan2
- HRNR | c.3391C>T p.R1131C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as rs1389056882; called by mutect2, varscan2
- HS6ST3 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs1484788053, COSV65010684; called by muse, mutect2
- HSPA12B | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs1164345942, COSV99421892; called by muse, mutect2, varscan2
- HTN3 | c.73-2A>G p.X25_splice | Splice Site (SNP) | VAF 253/583 reads (43%) | catalogued as COSV101126140; called by muse, mutect2, varscan2
- HTR1A | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.37); PolyPhen probably damaging (1); catalogued as COSV100108824; called by muse, mutect2, varscan2
- HUWE1 | c.6080G>T p.G2027V | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.448); catalogued as COSV99470189; called by muse, mutect2, varscan2
- HYKK | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV101194953; called by muse, mutect2, varscan2
- ID4 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.236); catalogued as COSV101099486; called by muse, mutect2
- IDH2 | c.435del p.T146Lfs*15 | Frame Shift Del (DEL) | VAF 54/133 reads (41%) | catalogued as rs747216375; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- IDI2 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs746906105, COSV52988034; called by muse, mutect2, varscan2
- IFT81 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 26/65 reads (40%) | catalogued as rs374954469; called by muse, mutect2, varscan2
- IGF2 | c.473C>T p.P158L (on ENST00000434045 / NM_001127598.3; = p.P102L on NM_000612.6) | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as rs369122420, COSV56096927; called by muse, mutect2, varscan2
- IGF2R | c.2557G>A p.A853T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV100806693; called by muse, mutect2, varscan2
- IGKV3D-15 | c.48A>G p.P16= | Splice Region (SNP) | VAF 28/96 reads (29%) | catalogued as rs1164051049; called by muse, mutect2, varscan2
- IL10 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558602814, CM106567, COSV65594400, COSV65594438; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1862A>G p.Q621R | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs371810135, COSV56295107, COSV56307243; called by muse, mutect2, varscan2
- IL27RA | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | catalogued as rs746755376, COSV54599991; called by muse, mutect2, varscan2
- ILDR1 | c.1178G>T p.R393M (on ENST00000344209 / NM_001199799.2; = p.R349M on NM_175924.4) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV56549931, COSV56554212; called by muse, mutect2, varscan2
- INO80D | c.2983C>T p.P995S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as COSV101305768; called by muse, mutect2, varscan2
- INTS3 | c.3086G>A p.R1029Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV99669624; called by muse, mutect2, varscan2
- INTS5 | c.569T>C p.M190T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100399401; called by muse, mutect2, varscan2
- IPO11 | c.2431A>G p.N811D | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1440095885, COSV100320159, COSV100321260; called by muse, varscan2
- IPO7 | c.3106G>T p.G1036W | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV101121758; called by muse, mutect2, varscan2
- IQGAP1 | c.2350-1G>A p.X784_splice | Splice Site (SNP) | VAF 25/58 reads (43%) | catalogued as COSV99184843; called by muse, mutect2, varscan2
- IRF4 | c.1325G>A p.R442K | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV101110730; called by muse, varscan2
- IRS4 | c.1772del p.G591Afs*20 | Frame Shift Del (DEL) | VAF 32/64 reads (50%) | catalogued as rs780982673; called by mutect2, varscan2
- ISYNA1 | c.370A>G p.S124G | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99525917; called by muse, mutect2, varscan2
- ITPRID2 | c.2995T>G p.F999V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as COSV100237748; called by muse, varscan2
- ITSN2 | c.106T>C p.S36P | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.246); catalogued as COSV100742525; called by muse, mutect2, varscan2
- JAKMIP3 | c.1645C>T p.R549W | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs761765135, COSV100058525; called by muse, mutect2, varscan2
- KANK2 | c.2158G>A p.E720K (on ENST00000586659 / NM_001379562.1; = p.E728K on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.094); catalogued as rs771164084, COSV100762971; called by muse, mutect2, varscan2
- KAT7 | c.1583T>C p.L528P | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99371550; called by muse, mutect2, varscan2
- KATNA1 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs748635170, COSV100167580; called by muse, mutect2, varscan2
- KCNA4 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV60255201; called by muse, mutect2, varscan2
- KCNC3 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100979141; called by muse, mutect2, varscan2
- KCNF1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54465684; called by muse, mutect2, varscan2
- KCNJ12 | c.768C>A p.D256E | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.886); catalogued as COSV100053881; called by muse, mutect2, varscan2
- KCNU1 | c.2735C>T p.T912M | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.805); catalogued as rs751479009, COSV67753197; called by muse, mutect2, varscan2
- KCTD12 | c.811T>C p.Y271H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.159); catalogued as COSV100499628; called by muse, mutect2, varscan2
- KDM2B | c.1897A>G p.M633V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV100997068; called by muse, mutect2, varscan2
- KDM5C | c.1741G>A p.V581M | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100948708; called by muse, mutect2, varscan2
- KIAA1586 | c.1454C>T p.A485V | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.88); PolyPhen benign (0.019); catalogued as rs375554795; called by muse, mutect2, varscan2
- KIAA1755 | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs746025973, COSV54076680; called by muse, varscan2
- KIAA1755 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775765046, COSV99641313; called by muse, mutect2, varscan2
- KIDINS220 | c.5215C>T p.R1739C | Missense Mutation (SNP) | VAF 80/227 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as rs749886554, COSV56758404; called by muse, mutect2, varscan2
- KIF26A | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100180618; called by muse, mutect2, varscan2
- KIF4A | c.2470G>T p.E824* | Nonsense Mutation (SNP) | VAF 23/48 reads (48%) | catalogued as COSV100790069; called by muse, mutect2, varscan2
- KIZ | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99851776; called by muse, mutect2, varscan2
- KLF17 | c.1114C>A p.P372T | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs746750521, COSV100954762, COSV64855900; called by muse, mutect2, varscan2
- KLHL1 | c.1912G>T p.G638W | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100916851; called by muse, mutect2, varscan2
- KLHL22 | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.48); PolyPhen benign (0.219); catalogued as rs149851344; called by muse, mutect2, varscan2
- KLHL26 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV99962935; called by muse, mutect2, varscan2
- KLK12 | c.623dup p.V209Sfs*71 (on ENST00000319590 / NM_001370127.1; = p.V209Sfs*41 on NM_019598.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 7/35 reads (20%) | catalogued as rs746582943; called by mutect2, pindel, varscan2
- KLK3 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as COSV58103169; called by muse, mutect2
- KLK8 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99143862; called by muse, mutect2, varscan2
- KLRC4 | c.160G>T p.G54W | Missense Mutation (SNP) | VAF 143/309 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58672557; called by muse, mutect2, varscan2
- KMT2C | c.13488del p.F4496Lfs*21 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as COSV51456416; called by mutect2, pindel, varscan2
- KMT2D | c.15545del p.G5182Afs*61 | Frame Shift Del (DEL) | VAF 12/23 reads (52%) | catalogued as COSV56464242; called by mutect2, varscan2
- KRTAP27-1 | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV101239657; called by muse, mutect2, varscan2
- KSR2 | c.1606del p.L536Sfs*61 | Frame Shift Del (DEL) | VAF 29/71 reads (41%) | catalogued as rs770565486; called by mutect2, pindel, varscan2
- LAMA4 | c.4474A>G p.K1492E (on ENST00000230538 / NM_001105206.3; = p.K1485E on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.341); catalogued as COSV100037398; called by muse, mutect2, varscan2
- LAMA5 | c.2816C>G p.A939G | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99437426; called by muse, mutect2, varscan2
- LARGE2 | c.2041A>G p.T681A | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated (0.8); PolyPhen benign (0.012); catalogued as COSV57660313; called by muse, mutect2, varscan2
- LBX2 | c.467C>T p.A156V (on ENST00000377566 / NM_001282430.2; = p.A152V on NM_001009812.2) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV52037256; called by muse, mutect2, varscan2
- LDOC1 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100983174, COSV65159206; called by muse, mutect2
- LEMD2 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768891530, COSV99540360; called by muse, mutect2, varscan2
- LGI4 | c.1501G>C p.A501P | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100032196; called by muse, mutect2, varscan2
- LGR6 | c.421C>T p.Q141* (on ENST00000367278 / NM_001017403.1; = p.Q89* on NM_021636.3) | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV99705801; called by muse, mutect2, varscan2
- LILRB1 | c.632G>A p.R211H (on ENST00000427581; = p.R175H on NM_006669.6) | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs112916853, COSV61116962, COSV61117136, COSV61121229; called by muse, varscan2
- LILRB5 | c.1335del p.T446Rfs*16 (on ENST00000449561 / NM_001081442.3; = p.T445Rfs*16 on NM_006840.5) | Frame Shift Del (DEL) | VAF 54/156 reads (35%) | catalogued as rs751333155; called by mutect2, pindel, varscan2
- LMTK2 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs763236901, COSV52006561; called by muse, mutect2, varscan2
- LMTK2 | c.3116C>T p.S1039F | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99805778; called by muse, mutect2, varscan2
- LNPK | c.785A>G p.Y262C | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs766545501, COSV99769831; called by muse, mutect2, varscan2
- LORICRIN | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 23/52 reads (44%) | PolyPhen benign (0.142); catalogued as COSV100907265; called by muse, varscan2
- LRFN5 | c.593C>A p.T198N | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1246086357, COSV99982035; called by muse, mutect2, varscan2
- LRP4 | c.3305T>C p.L1102P | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.864); catalogued as COSV101066099; called by muse, mutect2, varscan2
- LRP4 | c.1477C>T p.L493F | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs1249104943, COSV101066101; called by muse, mutect2, varscan2
- LRRC31 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1439194610, COSV52979718; called by muse, mutect2, varscan2
- LRRN4 | c.1758G>T p.Q586H | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV101125340; called by muse, mutect2, varscan2
- LY6K | c.29T>C p.V10A | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.012); catalogued as COSV99456074; called by muse, mutect2
- MAGEA12 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as COSV100756777; called by muse, mutect2, varscan2
- MAGI2 | c.685A>G p.I229V | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1200876428, COSV100831910; called by muse, mutect2, varscan2
- MAML2 | c.1219G>A p.V407I | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV101593911; called by muse, mutect2, varscan2
- MAML3 | c.2462A>G p.Q821R | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs763765311, COSV72210297; called by muse, mutect2
- MAMLD1 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs781882571, COSV53381307, COSV99475428; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.102A>G p.I34M | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61010700; called by muse, mutect2, varscan2
- MAP2K4 | c.634-1G>A p.X212_splice | Splice Site (SNP) | VAF 77/199 reads (39%) | catalogued as COSV100796075, COSV62255508; called by muse, mutect2, varscan2
- MAP3K1 | c.3028A>G p.I1010V | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101266037; called by muse, mutect2, varscan2
- MAP3K15 | c.2284A>G p.K762E | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV100133864; called by muse, mutect2, varscan2
- MAP3K9 | c.998G>A p.W333* | Nonsense Mutation (SNP) | VAF 3/23 reads (13%) | catalogued as COSV101173414; called by muse, mutect2, varscan2
- MAP4 | c.2755del p.R919Gfs*14 | Frame Shift Del (DEL) | VAF 50/138 reads (36%) | catalogued as rs778275488, COSV53142223; called by mutect2, pindel, varscan2
- MARK2 | c.1109G>A p.G370D | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1264871686, COSV100157928; called by muse, mutect2, varscan2
- MASP1 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs766084598, COSV51461074; called by muse, varscan2
- MAZ | c.605G>A p.G202D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as COSV99360749; called by muse, mutect2, varscan2
- MBD6 | c.2080del p.Q694Sfs*5 | Frame Shift Del (DEL) | VAF 8/15 reads (53%) | catalogued as rs762648935; called by mutect2, varscan2
- MBNL1 | c.452C>A p.P151Q | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.868); catalogued as COSV56826346, COSV56835920; called by muse, mutect2, varscan2
- MCEE | c.419del p.K140Rfs*6 | Frame Shift Del (DEL) | VAF 38/101 reads (38%) | catalogued as rs776473131; called by mutect2, varscan2
- MCHR2 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV56003624, COSV56009898; called by muse, mutect2, varscan2
- MCTP1 | c.2241+2T>C p.X747_splice | Splice Site (SNP) | VAF 31/82 reads (38%) | catalogued as COSV100385978; called by muse, mutect2, varscan2
- MDC1 | c.4562G>A p.R1521Q | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs753841715, COSV64527871; called by muse, mutect2, varscan2
- MED13 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs928823825, COSV101180700; called by muse, varscan2
- MED13 | c.103T>C p.W35R | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101180701; called by muse, varscan2
- MED23 | c.974del p.G325Efs*36 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | catalogued as rs770588171; called by mutect2, pindel, varscan2
- MEIS2 | c.158C>T p.A53V (on ENST00000561208 / NM_170675.5; = p.A40V on NM_002399.3) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.069); catalogued as COSV99575568; called by muse, mutect2, varscan2
- MESP2 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1180930085, COSV100510674; called by muse, varscan2
- METRNL | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368186952, COSV60761969; called by muse, mutect2, varscan2
- MFSD8 | c.929G>A p.G310D | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs118203975, CM073202, COSV99614085; ClinVar: uncertain significance; called by muse, varscan2
- MGAM | c.4519G>A p.V1507I | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.398); catalogued as rs527929510, COSV72075420, COSV72075783; called by muse, mutect2, varscan2
- MGAT5 | c.136C>A p.L46M | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99923901; called by muse, mutect2, varscan2
- MGAT5 | c.1063G>T p.G355* | Nonsense Mutation (SNP) | VAF 39/86 reads (45%) | catalogued as COSV56095363, COSV99923903; called by muse, mutect2, varscan2
- MIA2 | c.913T>G p.L305V | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as COSV54501906; called by muse, mutect2, varscan2
- MINDY2 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs773633276, COSV100376218; called by muse, varscan2
- MME | c.829A>G p.M277V | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.15); catalogued as COSV100852143; called by muse, varscan2
- MMS22L | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV99245888; called by muse, mutect2, varscan2
- MOGS | c.881del p.P294Lfs*11 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | catalogued as rs750486813; called by mutect2, pindel, varscan2
- MORC2 | c.2099T>C p.L700P (on ENST00000397641 / NM_001303256.3; = p.L638P on NM_014941.3) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs772866972, COSV99309332; called by muse, mutect2, varscan2
- MORF4L2 | c.577A>G p.M193V | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.353); catalogued as COSV64611489; called by muse, mutect2, varscan2
- MRGPRX4 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as rs1170513963, COSV100049611, COSV58589672; called by muse, mutect2, varscan2
- MROH2B | c.3482A>C p.E1161A | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV101270430; called by muse, mutect2, varscan2
- MRPL39 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs762645233, COSV100220785, COSV56260590; called by muse, mutect2, varscan2
- MSL3 | c.731A>G p.Y244C (on ENST00000312196 / NM_078629.4; = p.Y78C on NM_006800.4) | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.87); catalogued as rs1214224781, COSV56491451, COSV56496349; called by muse, varscan2
- MSS51 | c.1161C>T p.Y387= | Splice Region (SNP) | VAF 41/94 reads (44%) | catalogued as rs749585465, COSV55020852; called by muse, mutect2, varscan2
- MTA1 | c.1972T>C p.F658L | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV58760569; called by muse, mutect2, varscan2
- MTA3 | c.53C>A p.S18Y | Missense Mutation (SNP) | VAF 104/217 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199605489, COSV68136836; called by muse, mutect2, varscan2
- MTDH | c.1649C>G p.T550S | Missense Mutation (SNP) | VAF 99/157 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100292266, COSV60346376; called by muse, mutect2, varscan2
- MTX2 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV50889774; called by muse, mutect2, varscan2
- MUC16 | c.39543G>T p.E13181D | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.181); catalogued as COSV66696882; called by muse, mutect2, varscan2
- MUC20 | c.514C>A p.L172M | Missense Mutation (SNP) | VAF 68/319 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57855111; called by muse, varscan2
- MVK | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs371789705; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MXD3 | c.148del p.Q50Rfs*24 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | catalogued as rs866699857; called by pindel, varscan2
- MYBPH | c.14del p.N5Tfs*73 | Frame Shift Del (DEL) | VAF 29/72 reads (40%) | catalogued as rs752878638; called by mutect2, pindel, varscan2
- MYH9 | c.5573C>T p.A1858V | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV99337619; called by muse, mutect2, varscan2
- MYO15A | c.4753G>A p.A1585T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.831); catalogued as rs370901781; called by muse, mutect2
- MYO18A | c.2072G>A p.R691H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs189836557; called by muse, mutect2, varscan2
- MYO18B | c.530del p.P177Lfs*55 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs748007891; called by mutect2, varscan2
- MYO5C | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV99953897; called by muse, mutect2, varscan2
- MYO7B | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs749059672, COSV67346617; called by muse, mutect2, varscan2
- MYOCD | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs531377746, COSV58500836; called by muse, mutect2, varscan2
- MYOM3 | c.1684G>A p.V562I | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs183173497; called by muse, mutect2, varscan2
- MYRIP | c.305G>T p.W102L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100218096; called by muse, mutect2, varscan2
- NAALADL1 | c.1907G>A p.G636D | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100367859; called by muse, mutect2, varscan2
- NALCN | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs77946954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NANOS2 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs771133962, COSV100379432; called by muse, mutect2, varscan2
- NAP1L3 | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs749236135, COSV59074681; called by muse, mutect2, varscan2
- NAV1 | c.4685C>T p.T1562M | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs958041251, COSV99818022; called by muse, mutect2, varscan2
- NCAM1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs782428703, COSV57510729; called by muse, mutect2, varscan2
- NCKAP5L | c.3932del p.P1311Qfs*57 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | catalogued as rs750891910; called by mutect2, pindel, varscan2
- NCR3 | c.79A>T p.I27F | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as COSV99278812; called by muse, mutect2, varscan2
- NDC1 | c.1906G>T p.A636S | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.43); catalogued as COSV99323158; called by muse, mutect2, varscan2
- NDUFAB1 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV50287176, COSV99141436, COSV99141489; called by muse, mutect2, varscan2
- NEDD4 | c.1982G>A p.R661H (on ENST00000508342 / NM_001284338.1; = p.R242H on NM_006154.4) | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs369378356; called by muse, varscan2
- NEDD9 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760782051, COSV65219135; called by muse, mutect2, varscan2
- NEFL | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV99647786; called by muse, mutect2, varscan2
- NELFB | c.525dup p.L176Tfs*7 | Frame Shift Ins (INS) | VAF 8/25 reads (32%) | catalogued as rs1564441412; called by mutect2, pindel, varscan2
- NEUROG1 | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 21/38 reads (55%) | catalogued as rs748863808, COSV100130695; called by muse, mutect2, varscan2
- NF2 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); catalogued as CM001736, CX1111147, COSV100097027, COSV58525518; called by muse, mutect2, varscan2
- NFAT5 | c.701A>G p.H234R | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63027976, COSV63029287; called by muse, mutect2, varscan2
- NFIB | c.384G>A p.W128* | Nonsense Mutation (SNP) | VAF 31/87 reads (36%) | catalogued as COSV101100231; called by muse, mutect2, varscan2
- NID2 | c.3103del p.R1035Gfs*67 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as COSV53499514; called by mutect2, pindel
- NIPA2 | c.98dup p.L35Pfs*21 | Frame Shift Ins (INS) | VAF 20/77 reads (26%) | catalogued as rs145147241; called by mutect2, varscan2
- NOP14 | c.1903G>A p.V635M | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs768154236, COSV100054209; called by muse, mutect2, varscan2
- NOVA1 | c.907G>A p.V303I | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as COSV99946035; called by muse, mutect2, varscan2
- NOVA1 | c.101del p.P34Lfs*19 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | catalogued as rs765756993; called by mutect2, pindel, varscan2
- NPAP1 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.728); catalogued as rs1289511015, COSV61508546, COSV61510658; called by muse, mutect2, varscan2
- NPC1 | c.2432A>G p.Q811R | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as COSV99340641; called by muse, mutect2
- NPHS1 | c.2983G>T p.A995S | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.574); catalogued as rs1291134240, COSV100799539; called by muse, mutect2, varscan2
- NPHS1 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.76); catalogued as rs375631013, COSV100799541; called by muse, mutect2, varscan2
- NPPB | c.92G>T p.S31I | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.114); catalogued as COSV100916054; called by muse, mutect2, varscan2
- NPR3 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 25/51 reads (49%) | catalogued as rs774338813, COSV54089595; called by muse, mutect2, varscan2
- NR2C1 | c.1154C>A p.P385H | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100280107; called by muse, mutect2, varscan2
- NR2F2 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.166); catalogued as COSV101240898, COSV101240919; called by muse, mutect2, varscan2
- NRBF2 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.422); catalogued as COSV53260662; called by muse, mutect2, varscan2
- NRDC | c.965C>A p.A322D | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as COSV100702966; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 28/70 reads (40%) | catalogued as rs776154715; called by mutect2, varscan2
- NRXN1 | c.1851dup p.L618Afs*5 | Frame Shift Ins (INS) | VAF 33/78 reads (42%) | catalogued as rs768883697; called by mutect2, varscan2
- NRXN2 | c.4685C>T p.A1562V | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV99632056; called by muse, mutect2, varscan2
- NTRK2 | c.1984G>A p.A662T (on ENST00000323115 / NM_001369534.1; = p.A678T on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as rs1463968979, COSV52863308, COSV52874812; called by muse, mutect2, varscan2
- NUB1 | c.990del p.K330Nfs*2 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | catalogued as rs760102115; called by mutect2, varscan2
- NUGGC | c.1892del p.N631Ifs*3 | Frame Shift Del (DEL) | VAF 48/86 reads (56%) | catalogued as rs755498396, COSV58439694; called by mutect2, varscan2
- NUP93 | c.2006C>T p.S669F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV100359836; called by muse, mutect2, varscan2
- NYNRIN | c.2420G>A p.G807D | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101230474; called by muse, mutect2, varscan2
- OBSCN | c.20977del p.A6993Pfs*79 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs762005098; called by mutect2, pindel, varscan2
- OCA2 | c.2455G>A p.V819M | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.142); catalogued as COSV100666790; called by muse, mutect2, varscan2
- OCA2 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1199627951, COSV62352324; called by muse, mutect2, varscan2
- OLFML3 | c.163C>A p.L55M | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.434); catalogued as COSV100232905; called by muse, mutect2, varscan2
- OPN3 | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs780348058, COSV59363742; called by muse, mutect2, varscan2
- OPN3 | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV100086903; called by muse, mutect2, varscan2
- OR1G1 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs778622138, COSV100187477; called by muse, mutect2, varscan2
- OR2M3 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.95); PolyPhen benign (0.012); catalogued as rs547891650, COSV71759184, COSV71759200; called by muse, mutect2, varscan2
- OR4C16 | c.674A>C p.N225T | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.938); catalogued as COSV100113761; called by muse, mutect2, varscan2
- OR4C6 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.066); catalogued as rs146965889, COSV100051763; called by muse, mutect2, varscan2
- OR4E2 | c.893T>C p.M298T | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100329986; called by muse, mutect2, varscan2
- OR52L1 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs367627735; called by muse, mutect2, varscan2
- OR7D2 | c.293T>G p.L98R | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV60141418; called by muse, mutect2, varscan2
- OR8B3 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 101/232 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.102); catalogued as rs375945923, COSV100660336; called by muse, mutect2, varscan2
- OR9G1 | c.906dup p.L303Tfs*35 | Frame Shift Ins (INS) | VAF 9/52 reads (17%) | catalogued as rs1359495469; called by mutect2, pindel, varscan2
- OSR2 | c.178A>G p.N60D | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV99882169; called by muse, mutect2, varscan2
- OTOF | c.4852C>A p.R1618S (on ENST00000272371 / NM_194248.3; = p.R851S on NM_004802.4) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.09); catalogued as COSV99716206; called by muse, mutect2, varscan2
- OTUD4 | c.2711G>A p.G904D (on ENST00000447906 / NM_001366057.1; = p.G839D on NM_001102653.1) | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV101485856; called by muse, mutect2, varscan2
- PABPC5 | c.322A>G p.I108V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as COSV100442043, COSV57039089; called by muse, mutect2, varscan2
- PAFAH2 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs779769461, COSV100959186; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.544C>T p.R182C (on ENST00000259318 / NM_001136562.3; = p.R413C on NM_007203.5) | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as rs753146690, COSV52173242; called by muse, mutect2, varscan2
- PAOX | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs763052916, COSV53374877; called by muse, mutect2, varscan2
- PAQR9 | c.551A>G p.D184G | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.25); PolyPhen benign (0.079); catalogued as COSV61418736; called by muse, mutect2, varscan2
- PARD3B | c.2509del p.T837Rfs*13 (on ENST00000406610 / NM_001302769.2; = p.T768Rfs*13 on NM_057177.7) | Frame Shift Del (DEL) | VAF 74/214 reads (35%) | catalogued as rs772816756; called by mutect2, pindel, varscan2
- PARP15 | c.1220C>T p.A407V (on ENST00000464300 / NM_001113523.3; = p.A173V on NM_152615.2) | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); catalogued as COSV59973146; called by muse, mutect2, varscan2
- PASK | c.1906C>A p.L636I | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV99298443; called by muse, mutect2, varscan2
- PAX6 | c.1124dup p.H376Tfs*36 | Frame Shift Ins (INS) | VAF 18/53 reads (34%) | catalogued as rs756801119; called by mutect2, varscan2
- PBRM1 | c.3559G>A p.G1187R (on ENST00000296302 / NM_001366071.2; = p.G1162R on NM_018313.5) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56306145; called by muse, mutect2, varscan2
- PCDH10 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs1466602162, COSV99992683; called by muse, mutect2, varscan2
- PCDHA1 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1554117629, COSV65375684; called by muse, mutect2, varscan2
- PCDHA12 | c.1870G>A p.V624M | Missense Mutation (SNP) | VAF 94/213 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1462091033, COSV56475845; called by muse, mutect2, varscan2
- PCDHA13 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.066); catalogued as COSV99164864; called by muse, mutect2, varscan2
- PCDHB13 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs1311241816, COSV99506551; called by muse, mutect2, varscan2
- PCDHB4 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99521756; called by muse, mutect2, varscan2
- PCDHGA3 | c.566C>G p.A189G | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs779646542, COSV99528562; called by muse, mutect2, varscan2
- PCDHGA7 | c.425T>C p.I142T | Missense Mutation (SNP) | VAF 75/189 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as rs750393068, COSV99528565; called by muse, mutect2, varscan2
- PCDHGC3 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.417); catalogued as COSV52751363; called by muse, mutect2, varscan2
- PCF11 | c.838C>G p.R280G | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as COSV100017652, COSV100018380; called by muse, mutect2, varscan2
- PCGF1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1177968467, COSV99283141; called by muse, mutect2
- PCLO | c.11877A>G p.I3959M | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.05); catalogued as COSV61669234; called by muse, mutect2, varscan2
- PCNT | c.8800C>T p.L2934F | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100854945; called by muse, mutect2, varscan2
- PCOLCE2 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV99930261; called by muse, mutect2, varscan2
- PDCD7 | c.944T>C p.M315T | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52601493; called by muse, mutect2, varscan2
- PDE10A | c.2124A>G p.I708M | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV100604166, COSV63093266; called by muse, mutect2, varscan2
- PDK1 | c.1217C>A p.A406D | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV99961036; called by muse, mutect2, varscan2
- PDK3 | c.335T>A p.L112Q | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100998083; called by mutect2, varscan2
- PDS5A | c.2869G>A p.A957T | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100337072; called by muse, mutect2, varscan2
- PDZD2 | c.2942A>G p.D981G | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV99223238; called by muse, mutect2, varscan2
- PDZD8 | c.3271A>G p.M1091V | Missense Mutation (SNP) | VAF 75/201 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs770320221, COSV53693009; called by muse, mutect2, varscan2
- PEBP4 | c.651G>T p.K217N | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.298); catalogued as COSV99834404; called by muse, mutect2
- PEX6 | c.1907A>G p.Y636C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1053259449, COSV99769385; called by muse, mutect2, varscan2
- PFAS | c.1900G>A p.G634S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.788); catalogued as COSV100118706; called by muse, mutect2
- PGLYRP4 | c.187del p.A63Qfs*10 | Frame Shift Del (DEL) | VAF 14/33 reads (42%) | catalogued as COSV62836065; called by mutect2, pindel, varscan2
- PHETA2 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1169484956, COSV58790403; called by muse, mutect2, varscan2
- PHF14 | c.946del p.M316Wfs*5 | Frame Shift Del (DEL) | VAF 59/162 reads (36%) | catalogued as COSV68854594; called by mutect2, pindel, varscan2
- PHF20 | c.1073C>T p.T358M | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.333); catalogued as rs151029211; called by muse, mutect2, varscan2
- PHKB | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as rs192099645, COSV54515704; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PI4KA | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs141064047; called by muse, mutect2, varscan2
- PIDD1 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs920749342, COSV57194196; called by muse, mutect2, varscan2
- PIGQ | c.2203G>A p.V735I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); catalogued as rs575374982, COSV99215568; called by muse, mutect2, varscan2
- PIK3C2B | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs770614232, COSV65810279; called by muse, mutect2, varscan2
- PIK3CG | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100782413, COSV63252935; called by muse, mutect2, varscan2
- PIKFYVE | c.1058T>C p.V353A | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100009505; called by mutect2, varscan2
- PITX1 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.212); catalogued as rs773259804, COSV54763024; called by muse, mutect2, varscan2
- PLA1A | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56331072; called by muse, mutect2, varscan2
- PLA2G5 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as COSV100908178; called by muse, mutect2, varscan2
- PLA2R1 | c.3566A>G p.D1189G | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs902012721, COSV99321925; called by muse, mutect2, varscan2
- PLCB2 | c.2032G>A p.V678M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as rs755412316, COSV53035476; called by muse, mutect2, varscan2
- PLCG2 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774111706, COSV100842011; called by muse, mutect2, varscan2
- PLCL2 | c.2504A>G p.D835G (on ENST00000615277 / NM_001144382.2; = p.D709G on NM_015184.5) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs112342957, COSV101196511; called by mutect2, varscan2
- PLCZ1 | c.1745A>G p.Y582C | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99855713; called by muse, mutect2, varscan2
- PLEKHM1 | c.1539G>T p.Q513H | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0.264); catalogued as COSV69599469; called by muse, mutect2, varscan2
- PLG | c.1849G>A p.V617M | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100368664; called by muse, mutect2, varscan2
- PLXNA2 | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs774922495, COSV100884915; called by muse, mutect2, varscan2
- PLXNB1 | c.1636C>T p.R546* | Nonsense Mutation (SNP) | VAF 17/30 reads (57%) | catalogued as COSV99602066, COSV99603412; called by muse, mutect2, varscan2
- PLXNB2 | c.4316C>T p.A1439V | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as rs1410388747, COSV100833787; called by muse, mutect2, varscan2
- PLXNB2 | c.1616T>C p.L539P | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100833788; called by muse, varscan2
- PNMT | c.627dup p.H210Afs*27 | Frame Shift Ins (INS) | VAF 15/40 reads (38%) | catalogued as rs771451039; called by mutect2, pindel, varscan2
- PNO1 | c.412A>G p.K138E | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs755917828, COSV99718098; called by muse, mutect2, varscan2
- PNPLA5 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as COSV53376423; called by muse, mutect2, varscan2
- POLM | c.290del p.P97Qfs*6 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | catalogued as rs745933237; called by mutect2, pindel, varscan2
- POLR3F | c.515T>A p.F172Y | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101112265; called by muse, mutect2, varscan2
- POP4 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs565503123, COSV55676483; called by muse, mutect2, varscan2
- POU2F3 | c.522G>T p.K174N | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV99500598; called by muse, varscan2
- POU5F2 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as rs1266630516, COSV67939807; called by muse, mutect2, varscan2
- PPA2 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV58998744; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.778); catalogued as rs375262358, COSV99460626; called by muse, mutect2, varscan2
- PPFIA4 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769940708, COSV99829392; called by muse, mutect2, varscan2
- PPFIBP2 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs1026557911, COSV55075438, COSV55079766; called by muse, mutect2, varscan2
- PPIL1 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV101033743; called by muse, mutect2, varscan2
- PPP2R2C | c.218T>C p.F73S | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100065758; called by muse, mutect2, varscan2
- PPP3CA | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867473896, COSV59919482; called by muse, mutect2, varscan2
- PPP4R2 | c.496T>C p.S166P | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV55598152; called by muse, mutect2, varscan2
- PRB3 | c.725A>G p.H242R (on ENST00000381842; = p.H284R on NM_006249.5) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1453677875, COSV54392471; called by muse, mutect2, varscan2
- PRDM1 | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64845201; called by muse, mutect2, varscan2
- PRDM1 | c.2469G>T p.M823I | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.012); catalogued as COSV100958483; called by muse, mutect2, varscan2
- PRDM15 | c.1294G>A p.G432R | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.299); catalogued as rs781632486, COSV99519142; called by muse, mutect2, varscan2
- PRDM16 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.991); catalogued as rs1220568010, COSV99575176; called by muse, mutect2, varscan2
- PRDM9 | c.1468G>T p.G490* | Nonsense Mutation (SNP) | VAF 30/71 reads (42%) | catalogued as COSV57012599, COSV57012907; called by muse, mutect2, varscan2
- PRDM9 | c.1805A>G p.H602R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1382825002, COSV99689587; called by muse, varscan2
- PRIM1 | c.1103_1104del p.E368Gfs*3 | Frame Shift Del (DEL) | VAF 35/107 reads (33%) | catalogued as rs1219164714; called by pindel, varscan2
- PRKAR1B | c.260del p.P87Rfs*5 | Frame Shift Del (DEL) | VAF 12/21 reads (57%) | catalogued as rs764069617; called by mutect2, pindel, varscan2
- PRKCG | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs768380642, COSV54728018; called by muse, mutect2, varscan2
- PRPF6 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53865249; called by muse, mutect2, varscan2
- PRRC2C | c.371C>T p.A124V (on ENST00000367742; = p.A122V on NM_015172.4) | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100144499; called by muse, varscan2
- PRTFDC1 | c.196T>C p.Y66H | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100196641, COSV100197252; called by muse, mutect2, varscan2
- PSG9 | c.934A>T p.I312L | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.304); catalogued as COSV99391945; called by muse, mutect2, varscan2
- PTBP3 | c.1307A>G p.Q436R | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV100533928; called by muse, mutect2, varscan2
- PTCH1 | c.3386G>A p.G1129D | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59495085; called by muse, mutect2, varscan2
- PTCH2 | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs1346288458, COSV100941856; called by muse, mutect2, varscan2
- PTH1R | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100480731; called by muse, mutect2, varscan2
- PTPN21 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV60845906; called by muse, mutect2, varscan2
- PTPRD | c.2323T>C p.W775R | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV100642548, COSV61992484; called by muse, varscan2
- PTPRE | c.932T>C p.I311T | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.737); catalogued as rs1272790038, COSV99616628; called by muse, mutect2, varscan2
- PTPRN | c.92del p.G31Afs*75 | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | catalogued as rs1179811215; called by mutect2, varscan2
- PYGO2 | c.448dup p.Q150Pfs*27 | Frame Shift Ins (INS) | VAF 15/53 reads (28%) | catalogued as rs748504064; called by mutect2, varscan2
- PYHIN1 | c.424C>A p.P142T | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs780075398, COSV100932343, COSV63722905; called by muse, mutect2, varscan2
- QRICH2 | c.1406G>T p.R469I | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99428703; called by muse, mutect2, varscan2
- QSOX1 | c.1478G>A p.S493N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100852789; called by muse, mutect2, varscan2
- R3HCC1L | c.1949A>G p.D650G (on ENST00000612478 / NM_001256619.2; = p.D636G on NM_014472.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100106996; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3387dup p.A1130Sfs*9 | Frame Shift Ins (INS) | VAF 36/150 reads (24%) | catalogued as rs752866106; called by mutect2, varscan2
- RAB40C | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs145997805; called by muse, varscan2
- RABL2A | c.679del p.H227Tfs*10 | Frame Shift Del (DEL) | VAF 78/238 reads (33%) | catalogued as COSV100905609; called by mutect2, pindel, varscan2
- RAN | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 87/238 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV99619559; called by muse, mutect2, varscan2
- RANBP17 | c.3267A>G p.*1089Wext*96 | Nonstop Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as COSV101205965; called by muse, mutect2, varscan2
- RASGRF2 | c.3478G>T p.D1160Y | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99428294; called by muse, mutect2, varscan2
- RAVER1 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs768296431, COSV99532192; called by muse, mutect2, varscan2
- RC3H1 | c.768+2T>C p.X256_splice | Splice Site (SNP) | VAF 25/62 reads (40%) | catalogued as COSV99280897; called by muse, mutect2, varscan2
- RDH5 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs750520220, COSV57677479; called by muse, mutect2, varscan2
- RELN | c.3889C>T p.P1297S | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.965); catalogued as rs774353962, COSV100631946; called by muse, mutect2, varscan2
- REPIN1 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV101262563; called by muse, mutect2, varscan2
- REXO2 | c.655dup p.I219Nfs*3 | Frame Shift Ins (INS) | VAF 38/107 reads (36%) | catalogued as rs1338568560; called by mutect2, varscan2
- RHBDD2 | c.154T>C p.S52P | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs1554542000, COSV99138155; called by muse, mutect2, varscan2
- RILP | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs763922701, COSV99556770; called by muse, mutect2, varscan2
- RING1 | c.517del p.E173Kfs*14 | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | catalogued as rs761874510; called by mutect2, pindel, varscan2
- RIPK2 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.91); catalogued as COSV99609594; called by muse, mutect2, varscan2
- RNF41 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61505219; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 51/85 reads (60%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel
- ROBO1 | c.3600A>C p.E1200D | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV71398829; called by muse, mutect2, varscan2
- ROBO1 | c.1682C>A p.P561H | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV71398830; called by muse, mutect2, varscan2
- RPL10L | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs764186971, COSV100022301; called by muse, mutect2, varscan2
- RPS6KC1 | c.430T>G p.S144A | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100873734; called by muse, mutect2, varscan2
- RRH | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1399163854, COSV58492788; called by muse, mutect2, varscan2
- RRP1 | c.322A>G p.T108A | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV101513840; called by muse, mutect2, varscan2
- RRP12 | c.2569G>A p.A857T | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.141); catalogued as COSV100212805; called by muse, mutect2, varscan2
- RRP1B | c.543del p.K182Rfs*4 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | catalogued as rs1568956937; called by mutect2, pindel, varscan2
- RSPO4 | c.546G>T p.Q182H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as rs747525884, COSV99448693; called by muse, mutect2, varscan2
- RSRP1 | c.844del p.S282Vfs*20 | Frame Shift Del (DEL) | VAF 41/128 reads (32%) | catalogued as rs754096516; called by mutect2, pindel, varscan2
- RTKN2 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 43/111 reads (39%) | catalogued as rs756858537, COSV59524618; called by muse, mutect2, varscan2
- RTL9 | c.1733C>A p.P578Q | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs866117557, COSV101511599; called by muse, mutect2, varscan2
- RTP1 | c.709T>C p.C237R | Missense Mutation (SNP) | VAF 107/258 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.121); catalogued as COSV100398630; called by muse, mutect2, varscan2
- RUNDC3A | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as rs1420276191, COSV56589444; called by muse, mutect2, varscan2
- RUNX1T1 | c.1418G>A p.R473Q (on ENST00000265814 / NM_001198628.1; = p.R446Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.02); catalogued as rs774408067, COSV56146644; called by muse, mutect2, varscan2
- RUSC2 | c.1753del p.A585Pfs*62 | Frame Shift Del (DEL) | VAF 12/21 reads (57%) | catalogued as COSV100771001; called by mutect2, varscan2
- RUVBL2 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as rs779609047, COSV99668745; called by muse, varscan2
- RYR3 | c.9808C>T p.R3270C (on ENST00000389232; = p.R3271C on NM_001036.6) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs200295482, COSV101211811, COSV101213130; called by muse, mutect2
- SALL2 | c.2669T>C p.L890S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV100444055; called by muse, mutect2, varscan2
- SAMD7 | c.14C>A p.P5H | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100156693; called by muse, mutect2, varscan2
- SASH1 | c.3452A>G p.K1151R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as COSV100820830; called by muse, mutect2, varscan2
- SCFD1 | c.1600G>T p.G534* | Nonsense Mutation (SNP) | VAF 35/91 reads (38%) | catalogued as COSV100355930; called by muse, mutect2, varscan2
- SCGB1D1 | c.117A>C p.K39N | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as COSV100086593; called by muse, mutect2, varscan2
- SCLT1 | c.917C>T p.T306I | Missense Mutation (SNP) | VAF 218/534 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV55413248; called by muse, mutect2, varscan2
- SCN2A | c.2174G>A p.C725Y | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51856205; called by muse, mutect2, varscan2
- SCN8A | c.1855G>A p.G619S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.051); catalogued as COSV61993573; called by muse, mutect2, varscan2
- SCN9A | c.5328G>T p.E1776D (on ENST00000303354; = p.E1765D on NM_002977.3) | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV100310878; called by muse, mutect2, varscan2
- SDCBP2 | c.553C>T p.R185W (on ENST00000339987 / NM_001199784.1; = p.R100W on NM_015685.5) | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383253202, COSV60590514; called by muse, mutect2, varscan2
- SDHD | c.200C>T p.T67I | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV54779992; called by muse, mutect2, varscan2
- SDK2 | c.4282G>A p.G1428R | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs749315984, COSV101166587; called by muse, mutect2, varscan2
- SDK2 | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs367622362; called by muse, mutect2, varscan2
- SDS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs372154433; called by muse, mutect2, varscan2
- SEC11C | c.167G>A p.G56D | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.078); catalogued as COSV100230894; called by muse, mutect2, varscan2
- SEMA3C | c.1958C>T p.T653I | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV99542189; called by muse, mutect2, varscan2
- SEMA3F | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.96); catalogued as COSV99137163; called by muse, varscan2
- SEMA5B | c.173T>C p.I58T | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99530466; called by muse, mutect2, varscan2
- SEPTIN8 | c.515T>C p.M172T | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51524304; called by muse, mutect2, varscan2
- SERPINE1 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758271488, COSV99776519; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINI2 | c.575A>G p.K192R | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.763); catalogued as COSV52986523, COSV99247387; called by muse, mutect2, varscan2
- SETD1A | c.4819G>A p.A1607T | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99352221; called by muse, mutect2, varscan2
- SHANK1 | c.1186G>A p.G396R | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99519955; called by muse, mutect2, varscan2
- SHC2 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1363414078, COSV99198900; called by muse, mutect2, varscan2
- SHROOM4 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs782548063, COSV56792899; called by muse, mutect2, varscan2
- SIPA1L2 | c.3343G>A p.D1115N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.097); catalogued as rs566304161, COSV53384673; called by muse, mutect2, varscan2
- SLC13A1 | c.1419A>G p.I473M | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV99520229; called by muse, mutect2, varscan2
- SLC13A3 | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.05); catalogued as rs757716165, COSV99285938; called by muse, mutect2, varscan2
- SLC16A6 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100517141; called by muse, mutect2, varscan2
- SLC1A6 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs148535335; called by muse, mutect2, varscan2
- SLC22A4 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52360413; called by muse, mutect2, varscan2
- SLC25A23 | c.721C>A p.L241M | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.883); catalogued as COSV99901775; called by muse, mutect2, varscan2
- SLC25A31 | c.582G>T p.Q194H | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.813); catalogued as COSV99829147; called by muse, mutect2, varscan2
- SLC25A4 | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV99861148; called by muse, mutect2, varscan2
- SLC25A42 | c.532T>C p.S178P | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.803); catalogued as COSV100587989; called by muse, mutect2, varscan2
- SLC26A2 | c.131C>T p.T44I | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV99639932; called by muse, mutect2
- SLC26A9 | c.1885C>A p.P629T | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV61605448, COSV61605685; called by muse, mutect2, varscan2
- SLC28A2 | c.142del p.D48Mfs*52 | Frame Shift Del (DEL) | VAF 30/96 reads (31%) | catalogued as rs1567054883; called by mutect2, pindel, varscan2
- SLC29A1 | c.1291G>T p.G431* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100505514; called by muse, mutect2, varscan2
- SLC29A2 | c.1309_1311del p.F437del | In Frame Del (DEL) | VAF 15/46 reads (33%) | catalogued as rs754664833; called by pindel, varscan2
- SLC29A4 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV99786568; called by muse, mutect2, varscan2
- SLC35G3 | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); catalogued as COSV99268063; called by muse, mutect2, varscan2
- SLC35G5 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99643846; called by muse, mutect2, varscan2
- SLC35G6 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100262503; called by muse, mutect2, varscan2
- SLC37A3 | c.882G>A p.P294= | Splice Region (SNP) | VAF 20/57 reads (35%) | catalogued as rs770276475, COSV100405209; called by muse, mutect2, varscan2
- SLC39A14 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.148); catalogued as rs753123757, COSV51485459, COSV99249495; called by muse, mutect2, varscan2
- SLC4A4 | c.2827C>T p.R943C (on ENST00000264485 / NM_001098484.3; = p.R899C on NM_003759.4) | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52623568; called by muse, mutect2, varscan2
- SLC5A10 | c.1207C>T p.R403C (on ENST00000395645 / NM_001042450.4; = p.R419C on NM_152351.5) | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs574275296, COSV100524702; called by muse, mutect2, varscan2
- SLC6A1 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 40/43 reads (93%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV55114842; called by muse, mutect2, varscan2
- SLC6A2 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557196282, COSV54921528; called by muse, mutect2, varscan2
- SLC6A5 | c.1128G>A p.K376= | Splice Region (SNP) | VAF 17/41 reads (41%) | catalogued as rs532759670, COSV100116221; called by muse, mutect2, varscan2
- SLC6A5 | c.2047T>C p.F683L | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as COSV100116234; called by muse, mutect2, varscan2
- SLC7A10 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs78277336, COSV99471877; called by muse, mutect2, varscan2
- SLC7A3 | c.954G>C p.E318D | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs1249355870, COSV99979254; called by muse, mutect2, varscan2
- SLCO4A1 | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.022); catalogued as rs368075379; called by muse, mutect2, varscan2
- SLCO4C1 | c.1703G>T p.G568V | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100194388, COSV60513691; called by muse, mutect2, varscan2
- SLCO5A1 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52668787, COSV99479179; called by muse, mutect2, varscan2
- SLCO6A1 | c.1625del p.K542Rfs*13 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | catalogued as rs866444182; called by mutect2, varscan2
683 further variants in this file (364 protein-altering or splice-affecting, 293 silent, 26 other) are not listed here.
